MMRF case MMRF_1195 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b5c025c8-845f-4952-9eb5-71e979b3f35e

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.7 years (22,172 days); ISS stage: I; Days to last known disease status: 676 days (1.9 years); Days to last follow up: 676 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 108 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 107 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 109 days; Days to treatment end: 109 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: M Protein 7.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 357 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 47.4 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 3.03 mmol/L; Albumin 40 g/L; Total Protein 11.1 g/dL; Glucose 5.89 mmol/L.
- Day 88: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 9.29 g/L; Immunoglobulin A 0.677 g/L; Immunoglobulin M 0.366 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 343 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.89 mmol/L.
- Day 141: M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.5 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 268: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.7 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.17 mmol/L.
- Day 337 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.5 mmol/L; Platelets 323 ×10⁹/L.
- Day 393: M Protein 0 g/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.1 ×10⁹/L; Platelets 260 ×10⁹/L.
- Day 515 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 4.18 mmol/L.
- Day 676 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 1.66 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day -3: Weight: 92 kg; Height: 174 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1195_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1195_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
